Somatic mutation profile of tumor specimen 0E1SY3 from CCDI case PBCUEN, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: male.
Specimen 0E1SY3: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 9fa28f56-cb55-4760-94e9-2bf79d003c1c.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0E1SXX (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/b9167c1e-1d93-4d89-928e-0c1f252c862a

The open-access MAF lists 24 somatic variants for this specimen: 15 protein-altering or splice-affecting, 3 silent, 6 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 12, Silent 3, 3'UTR 3, RNA 2, Nonsense Mutation 1, Splice Region 1, Frame Shift Ins 1, 3'Flank 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ASH1L | c.1252A>G p.S418G | Missense Mutation (SNP) | VAF 106/220 reads (48%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0); catalogued as rs1398058487; called by muse, mutect2, varscan2
- MUC16 | c.27775C>A p.P9259T | Missense Mutation (SNP) | VAF 44/102 reads (43%) | SIFT tolerated, low confidence (1); PolyPhen benign (0.047); catalogued as COSV67484030; called by muse, varscan2
- PCDHGA11 | c.668G>A p.R223Q | Missense Mutation (SNP) | VAF 34/113 reads (30%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.133); catalogued as COSV53914568; called by muse, mutect2, varscan2
- PIWIL1 | c.460G>A p.E154K | Missense Mutation (SNP) | VAF 185/697 reads (27%) | SIFT tolerated (0.4); PolyPhen benign (0.028); catalogued as rs369491337; called by muse, mutect2, varscan2
- AADAC | c.1027G>C p.D343H | Missense Mutation (SNP) | VAF 12/310 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- CCDC18 | c.3880A>T p.K1294* (on ENST00000343253 / NM_001306076.1; = p.K1295* on NM_206886.4) | Nonsense Mutation (SNP) | VAF 20/190 reads (11%) | called by muse, varscan2
- CDV3 | c.627-3T>A | Splice Region (SNP) | VAF 14/147 reads (10%) | called by muse, varscan2
- CREBBP | c.1092_1093dup p.H365Lfs*25 | Frame Shift Ins (INS) | VAF 94/220 reads (43%) | called by mutect2, varscan2
- DMC1 | c.757C>A p.L253I | Missense Mutation (SNP) | VAF 90/224 reads (40%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.945); called by muse, mutect2, varscan2
- ELAPOR1 | c.217C>T p.P73S | Missense Mutation (SNP) | VAF 69/160 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- MRGPRE | c.156T>G p.N52K | Missense Mutation (SNP) | VAF 37/37 reads (100%) | SIFT tolerated (0.3); PolyPhen benign (0.117); called by muse, mutect2, varscan2
- SERPINA3 | c.292G>A p.E98K | Missense Mutation (SNP) | VAF 25/121 reads (21%) | SIFT deleterious (0); PolyPhen possibly damaging (0.907); called by muse, mutect2, varscan2
- SNTG1 | c.1044T>A p.S348R | Missense Mutation (SNP) | VAF 133/285 reads (47%) | SIFT tolerated (0.34); PolyPhen benign (0.205); called by muse, mutect2, varscan2
- USP17L4 | c.581A>T p.H194L | Missense Mutation (SNP) | VAF 10/166 reads (6%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.862); called by muse, varscan2
- ZNF510 | c.742C>G p.Q248E | Missense Mutation (SNP) | VAF 23/528 reads (4%) | SIFT tolerated (0.08); PolyPhen benign (0.014); called by muse, mutect2
- FLNB | c.3429C>T p.L1143= | Silent (SNP) | VAF 5/130 reads (4%) | catalogued as rs937646550, COSV55893305; called by muse, mutect2
- OR1N1 | c.816A>T p.A272= | Silent (SNP) | VAF 8/156 reads (5%) | called by muse, mutect2
- OR6P1 | c.735G>T p.L245= | Silent (SNP) | VAF 34/388 reads (9%) | called by muse, mutect2
- AC129492.5 | n.82G>T | RNA (SNP) | VAF 8/49 reads (16%) | called by mutect2, varscan2
- ANKRD40CL | chr17:50761267 A>T | 3'Flank (SNP) | VAF 4/41 reads (10%) | called by muse, mutect2
- CACNB4 | c.*95T>A | 3'UTR (SNP) | VAF 9/73 reads (12%) | called by muse, varscan2
- FOXP3 | c.*61G>T | 3'UTR (SNP) | VAF 5/47 reads (11%) | called by muse, mutect2
- LINC02694 | n.551T>C | RNA (SNP) | VAF 8/94 reads (9%) | called by muse, mutect2
- NTNG2 | c.*83G>A | 3'UTR (SNP) | VAF 3/22 reads (14%) | catalogued as rs1455184280; called by muse, varscan2
